Somatic mutation profile of tumor specimen TCGA-ZG-A9L6-01A (aliquot TCGA-ZG-A9L6-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9L6, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.8 years (23,681 days).
Specimen TCGA-ZG-A9L6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7691f24-0d94-4879-9463-8000f47e6231.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9L6-10A (Blood Derived Normal), aliquot TCGA-ZG-A9L6-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82e5804d-82b4-4639-bd8c-3ad3b3246feb

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 21, Silent 9, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.65T>G p.L22R | Missense Mutation (SNP) | VAF 18/115 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV69042031, COSV69042523, COSV69043220; called by muse, mutect2, varscan2
- SPOP | c.391T>C p.W131R | Missense Mutation (SNP) | VAF 18/124 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV61652911, COSV61653817; called by muse, mutect2, varscan2
- AKR1A1 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.61); catalogued as COSV100698709; called by muse, mutect2
- CAMK1G | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV99151667; called by muse, mutect2
- CD72 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs368007396; called by muse, varscan2
- CELF2 | c.613A>G p.I205V (on ENST00000416382 / NM_001025077.3; = p.I212V on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100257280; called by muse, mutect2
- CWH43 | c.1000A>G p.T334A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV99893254; called by muse, mutect2, varscan2
- EARS2 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs755318395, COSV101492163; called by muse, mutect2, varscan2
- EIF5 | c.984G>C p.Q328H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1405975503, COSV99384747; called by muse, mutect2, varscan2
- FUT8 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100651317; called by muse, mutect2, varscan2
- MN1 | c.2471G>T p.C824F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1409219109, COSV100179789; called by mutect2, varscan2
- OR5L1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs138368201; called by muse, mutect2
- PAX1 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.048); catalogued as COSV68273520; called by muse, mutect2
- PCDHA9 | c.1303C>G p.L435V | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1356253349, COSV100969395; called by muse, mutect2, varscan2
- POSTN | c.896-1G>C p.X299_splice | Splice Site (SNP) | VAF 3/30 reads (10%) | catalogued as COSV101123309; called by muse, mutect2
- PPIL4 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.047); catalogued as COSV99481604; called by muse, mutect2, varscan2
- PRPSAP2 | c.1075T>A p.S359T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV52065157, COSV99264472; called by muse, mutect2, varscan2
- SDSL | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.024); catalogued as COSV100615223, COSV61884628; called by muse, mutect2, varscan2
- SERPINB9 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs1187342686, COSV101046556; called by muse, mutect2, varscan2
- SLC2A5 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs138176474; called by muse, mutect2, varscan2
- SLITRK1 | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV65674814; called by muse, mutect2
- THSD4 | c.2135T>C p.L712P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99965199; called by muse, mutect2, varscan2
- IL21 | c.414_415del p.R139Ifs*16 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- ELMO2 | c.999C>A p.A333= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99281611; called by muse, mutect2, varscan2
- EMSY | c.1860G>A p.K620= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV100595614; called by muse, mutect2
- LINGO4 | c.1605G>A p.V535= | Silent (SNP) | VAF 21/155 reads (14%) | catalogued as COSV100764985; called by muse, mutect2, varscan2
- OR10G3 | c.144T>A p.T48= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100336084; called by muse, mutect2
- PIGT | c.1587C>A p.I529= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99648879; called by muse, mutect2
- PIP5K1C | c.1641G>A p.P547= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs756701195, COSV58949958; called by muse, mutect2, varscan2
- SARDH | c.1350G>A p.T450= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs371233114, COSV100898429; called by muse, mutect2, varscan2
- TNKS2 | c.1162A>C p.R388= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100861056; called by muse, mutect2
- USH2A | c.7017A>G p.T2339= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as rs1426861450, COSV100233083; called by muse, mutect2, varscan2
